Somatic mutation profile of tumor specimen 0DCM1M from CCDI case PBBMCH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 6.4 years (2,325 days).
Specimen 0DCM1M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1c84dfd-a38b-4f75-b4e8-c36f03932aa2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCM1A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57e537d0-1b92-4205-a6b1-1123e7405d90

The open-access MAF lists 58 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Intron 10, Silent 10, 3'UTR 4, RNA 3, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>C p.D32A | Missense Mutation (SNP) | VAF 108/577 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 354/610 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- ADGRV1 | c.9920A>G p.E3307G | Missense Mutation (SNP) | VAF 125/478 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1320958543, COSV67979865; called by muse, mutect2, varscan2
- ALOX12 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 108/232 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.728); catalogued as COSV52353067, COSV99278241; called by muse, mutect2, varscan2
- AWAT2 | c.198C>T p.G66= | Splice Region (SNP) | VAF 121/422 reads (29%) | catalogued as rs778711541; called by muse, mutect2, varscan2
- COL26A1 | c.649G>A p.G217R (on ENST00000313669 / NM_001278563.3; = p.G215R on NM_133457.4) | Missense Mutation (SNP) | VAF 180/450 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1169856215; called by muse, mutect2, varscan2
- CYP4F12 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 145/947 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV61173292; called by muse, mutect2, varscan2
- MASP1 | c.628T>A p.S210T | Missense Mutation (SNP) | VAF 192/828 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs1415745097; called by muse, mutect2, varscan2
- NADSYN1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 39/852 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs1356105492, COSV59809678; called by muse, mutect2
- PIH1D2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 285/955 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs781970407; called by muse, mutect2, varscan2
- PRR23C | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 167/811 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV68827028; called by muse, mutect2, varscan2
- RYR2 | c.13490G>C p.R4497P | Missense Mutation (SNP) | VAF 265/613 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63677657; called by muse, mutect2, varscan2
- TNS1 | c.3541C>T p.R1181C | Missense Mutation (SNP) | VAF 160/680 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as rs773542085, COSV50692560; called by muse, mutect2, varscan2
- BRWD3 | c.3070T>C p.Y1024H | Missense Mutation (SNP) | VAF 174/465 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CALR3 | c.446A>C p.H149P | Missense Mutation (SNP) | VAF 250/851 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CRACD | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 94/437 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DNAJC6 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 241/538 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, varscan2
- FGF12 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 78/720 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- HTR3A | c.702C>A p.F234L | Missense Mutation (SNP) | VAF 195/601 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- IGSF9B | c.2867C>A p.P956H | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- INSR | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 163/555 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IQSEC2 | c.2788G>T p.V930L (on ENST00000642864 / NM_001111125.3; = p.V725L on NM_015075.2) | Missense Mutation (SNP) | VAF 143/434 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- KLC2 | c.851C>A p.T284K | Missense Mutation (SNP) | VAF 36/526 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- P2RX3 | c.383C>G p.P128R | Missense Mutation (SNP) | VAF 33/670 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.049); called by muse, mutect2
- RPUSD4 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 181/555 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- RWDD3 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 419/896 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC1A3 | c.155T>G p.L52R | Missense Mutation (SNP) | VAF 94/1120 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- USP34 | c.6234G>T p.K2078N | Missense Mutation (SNP) | VAF 39/851 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- ZAN | c.4072C>A p.L1358M | Missense Mutation (SNP) | VAF 117/403 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZEB2 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 231/872 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ABCA9 | c.4230G>T p.L1410= | Silent (SNP) | VAF 146/778 reads (19%) | called by mutect2, varscan2
- ATP2B3 | c.2415G>A p.A805= | Silent (SNP) | VAF 78/280 reads (28%) | catalogued as rs1340289205; called by muse, mutect2, varscan2
- CDYL2 | c.678G>A p.A226= | Silent (SNP) | VAF 48/938 reads (5%) | catalogued as rs531982053, COSV73653970; called by muse, mutect2
- CHST15 | c.630C>G p.T210= | Silent (SNP) | VAF 232/539 reads (43%) | catalogued as rs1376361084; called by muse, mutect2, varscan2
- DCAF4L2 | c.1077G>A p.S359= | Silent (SNP) | VAF 90/598 reads (15%) | catalogued as rs754142692, COSV60483251; called by muse, mutect2, varscan2
- GABRQ | c.1419T>G p.A473= | Silent (SNP) | VAF 160/491 reads (33%) | called by muse, mutect2, varscan2
- HPS5 | c.1740A>G p.E580= (on ENST00000349215 / NM_181507.2; = p.E466= on NM_007216.4) | Silent (SNP) | VAF 237/848 reads (28%) | catalogued as rs1458415208; called by muse, varscan2
- IL1RN | c.489C>T p.D163= (on ENST00000409930 / NM_173842.3; = p.D145= on NM_000577.5) | Silent (SNP) | VAF 197/714 reads (28%) | catalogued as rs371472986; called by muse, mutect2, varscan2
- RBM14 | c.1902T>C p.D634= | Silent (SNP) | VAF 111/735 reads (15%) | called by muse, mutect2, varscan2
- ZNF615 | c.609C>T p.A203= | Silent (SNP) | VAF 162/598 reads (27%) | called by muse, mutect2, varscan2
- CSMD3 | c.917+88T>G | Intron (SNP) | VAF 80/334 reads (24%) | called by muse, mutect2, varscan2
- CTRL | c.157-19C>T | Intron (SNP) | VAF 75/266 reads (28%) | called by muse, mutect2, varscan2
- EIF3F | c.515+81T>C | Intron (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
- FTHL18 | n.285C>T | RNA (SNP) | VAF 50/404 reads (12%) | catalogued as rs1162634661; called by muse, mutect2, varscan2
- HBP1 | c.1527+35G>A | Intron (SNP) | VAF 92/239 reads (38%) | called by muse, mutect2, varscan2
- IKZF2 | c.*66del | 3'UTR (DEL) | VAF 22/66 reads (33%) | called by mutect2, varscan2
- INPP5J | c.1899+46C>T | Intron (SNP) | VAF 48/115 reads (42%) | catalogued as rs751672094, COSV58511886; called by muse, mutect2, varscan2
- ITGB1BP1 | c.532-87G>A | Intron (SNP) | VAF 12/38 reads (32%) | catalogued as rs934285496; called by muse, mutect2, varscan2
- MUC19 | n.12327T>A | RNA (SNP) | VAF 123/592 reads (21%) | catalogued as rs1335497961; called by mutect2, varscan2
- MUC19 | n.19336dup | RNA (INS) | VAF 190/560 reads (34%) | called by mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 6/69 reads (9%) | called by muse, varscan2
- PRDM11 | chr11:45224976 C>T | 3'Flank (SNP) | VAF 92/242 reads (38%) | catalogued as rs1024367293, COSV55440512; called by muse, mutect2, varscan2
- SHISA9 | c.*85C>A | 3'UTR (SNP) | VAF 30/42 reads (71%) | called by muse, mutect2, varscan2
- TAOK3 | c.988-22C>A | Intron (SNP) | VAF 42/221 reads (19%) | called by muse, mutect2, varscan2
- TP63 | c.1350-6147A>G | Intron (SNP) | VAF 26/484 reads (5%) | catalogued as rs985640582, COSV53195737; called by muse, mutect2
- USP5 | c.*30C>A | 3'UTR (SNP) | VAF 14/252 reads (6%) | called by muse, mutect2
- VCAN | c.*8A>T | 3'UTR (SNP) | VAF 95/516 reads (18%) | called by muse, mutect2, varscan2
- ZNF599 | c.241+17C>G | Intron (SNP) | VAF 52/206 reads (25%) | called by muse, mutect2, varscan2
